MMRF case MMRF_2379 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2d52b7cf-a5b5-4c86-9aee-b273896cbe95

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 79 years; Vital status: Dead; Days to death: 90 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 79.6 years (29,070 days); ISS stage: III; Days to last known disease status: 90 days; Days to last follow up: 90 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 83 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 90.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 18.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5936 mg/dL; Immunoglobulin G 5.64 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 7.7 µg/mL; Hemoglobin 6.45 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.6 mmol/L; Glucose 6.16 mmol/L.
- Day 63 (ECOG 0): Immunoglobulin G 3.22 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.35 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 46 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 1.98 mmol/L; Albumin 32 g/L; Total Protein 5.3 g/dL; Glucose 8.2 mmol/L.

Other clinical attributes
- Day -20: Weight: 82 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2379_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2379_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
